CCDI case PBCKDM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/eb8c7a41-41cd-4158-8230-f5734f8eb6fc

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.6 years (6,061 days).

Biospecimens (3 samples)
- Sample 0DTREB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTREI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTREP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
